Somatic mutation profile of tumor specimen 0E03V5 from CCDI case PBCUCN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E03V5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 803b4f97-5a0d-4132-905a-273b92c179a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E03W1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef0b45c-c3b1-4f39-8cfd-7e1f23f50326

The open-access MAF lists 246 somatic variants for this specimen: 152 protein-altering or splice-affecting, 56 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 56, Intron 16, 5'UTR 11, 3'UTR 9, Splice Region 5, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 110/305 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- ABCA4 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 323/815 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV64673070; called by muse, mutect2, varscan2
- ABCA6 | c.4030-1G>A p.X1344_splice | Splice Site (SNP) | VAF 249/496 reads (50%) | catalogued as COSV52645316; called by muse, mutect2, varscan2
- ADAL | c.856C>T p.H286Y (on ENST00000562188 / NM_001324366.2; = p.H259Y on NM_001159280.3) | Missense Mutation (SNP) | VAF 377/697 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67501318; called by muse, mutect2, varscan2
- AGL | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 244/589 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769850309; called by muse, mutect2, varscan2
- AHSG | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 200/523 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99889933; called by muse, mutect2, varscan2
- ATXN7L1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 252/665 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV69308703; called by muse, mutect2, varscan2
- CAMTA1 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 179/251 reads (71%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs139090441; called by muse, mutect2, varscan2
- CAPN12 | c.804+5G>A | Splice Region (SNP) | VAF 130/327 reads (40%) | catalogued as rs762456752; called by muse, mutect2, varscan2
- CCDC66 | c.2209G>A p.E737K (on ENST00000394672 / NM_001353147.1; = p.E703K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 266/651 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58309257; called by muse, mutect2, varscan2
- CLEC16A | c.917C>A p.P306Q | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV68499806; called by muse, mutect2, varscan2
- COL3A1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV58597120; called by muse, mutect2, varscan2
- CTDP1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 170/413 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769147755; called by muse, varscan2
- CTIF | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs150436238; called by muse, varscan2
- CYP27B1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 147/537 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as rs1055335288; called by muse, mutect2, varscan2
- DCAF12L1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs1318593946; called by muse, mutect2, varscan2
- DCP1A | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 287/724 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs267599901, COSV53688037; called by muse, mutect2, varscan2
- DENND4B | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 116/440 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs373737768; called by muse, mutect2, varscan2
- DEPTOR | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 263/622 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53813015; called by muse, mutect2, varscan2
- DLG3 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 168/444 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1400725871; called by muse, mutect2, varscan2
- DSG4 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750739975; called by muse, mutect2, varscan2
- DST | c.14026G>A p.A4676T (on ENST00000361203 / NM_001374722.1; = p.A2264T on NM_015548.5) | Missense Mutation (SNP) | VAF 153/469 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs1367127828, COSV55035586; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100918942; called by muse, mutect2, varscan2
- FAM110A | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 216/482 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs1450419084; called by muse, mutect2, varscan2
- FAT4 | c.11285C>T p.T3762M | Missense Mutation (SNP) | VAF 274/479 reads (57%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1448470488; called by muse, varscan2
- FBLN2 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 172/431 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367760110; called by muse, mutect2, varscan2
- FLT4 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 185/566 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs920759638, COSV56126896; called by muse, mutect2, varscan2
- GINS1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 247/573 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762561743; called by muse, mutect2, varscan2
- GLRA4 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs768921526, COSV60327928; called by muse, mutect2, varscan2
- GZF1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs891711571, COSV100582482; called by muse, mutect2, varscan2
- HDAC7 | c.329C>T p.P110L (on ENST00000427332; = p.P149L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 280/505 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352450121, COSV50319335; called by muse, mutect2, varscan2
- IL9R | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 37/567 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs201133561, COSV54898957; called by muse, mutect2
- INTS10 | c.442-1G>A p.X148_splice | Splice Site (SNP) | VAF 169/473 reads (36%) | catalogued as COSV67605067; called by muse, mutect2, varscan2
- KRT3 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 297/1235 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs760545335; called by muse, mutect2, varscan2
- LAMA3 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 176/524 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV58070235; called by muse, mutect2, varscan2
- LRRTM4 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 238/884 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186071356, COSV69141370; called by muse, mutect2, varscan2
- MATN4 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 150/740 reads (20%) | PolyPhen probably damaging (0.988); catalogued as rs533805250; called by muse, varscan2
- MIGA2 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 97/259 reads (37%) | catalogued as rs772417964, COSV52977154; called by muse, mutect2, varscan2
- MUC17 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 177/520 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1409607798; called by muse, mutect2, varscan2
- NAB1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 353/685 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs772814531, COSV61609310; called by muse, mutect2, varscan2
- NDC1 | c.57C>T p.R19= | Splice Region (SNP) | VAF 175/444 reads (39%) | catalogued as rs761732272; called by muse, mutect2, varscan2
- NLRP4 | c.2143T>A p.C715S | Missense Mutation (SNP) | VAF 579/872 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV56715542; called by muse, mutect2, varscan2
- NPIPA5 | c.517T>A p.L173M | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64114943; called by muse, mutect2, varscan2
- NUDT12 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 152/438 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as COSV50092084; called by muse, varscan2
- NXF3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 138/339 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs764974230, COSV67703146; called by muse, mutect2, varscan2
- PAPPA2 | c.4037C>T p.S1346L | Missense Mutation (SNP) | VAF 98/609 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1453407973, COSV62790237; called by muse, mutect2, varscan2
- PBX3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs774888450, COSV60732643; called by muse, mutect2, varscan2
- PCDHB11 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as rs549292417; called by muse, varscan2
- PDZD7 | c.1999G>A p.V667M | Missense Mutation (SNP) | VAF 168/433 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1283190924; called by muse, mutect2, varscan2
- PHF6 | c.644G>A p.C215Y (on ENST00000332070 / NM_032458.3; = p.C216Y on NM_032335.3) | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59699867; called by muse, mutect2, varscan2
- PRG4 | c.3659C>T p.T1220I | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770892416; called by muse, mutect2, varscan2
- PTGER3 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 265/652 reads (41%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV100138518; called by muse, mutect2, varscan2
- RBM27 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 222/617 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1219915064, COSV54592500; called by muse, mutect2, varscan2
- RBM43 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 227/780 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100508536; called by muse, mutect2, varscan2
- RBMXL2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 150/465 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as COSV60979895; called by muse, mutect2
- RHO | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 121/524 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs538820015, COSV56212477; called by muse, mutect2, varscan2
- RNF213 | c.9649G>A p.V3217I | Missense Mutation (SNP) | VAF 250/460 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs767748024, COSV60395402; called by muse, mutect2, varscan2
- RPL5 | c.74-7del | Splice Region (DEL) | VAF 146/762 reads (19%) | catalogued as COSV59873487; called by pindel, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 91/292 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- SLC10A7 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1258444035; called by muse, mutect2, varscan2
- SLC43A2 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as rs148869741; called by muse, mutect2, varscan2
- SMARCC2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 468/870 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57221991; called by muse, mutect2, varscan2
- TCERG1L | c.1082C>A p.T361K | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV64051704; called by mutect2, varscan2
- TNRC18 | c.6934G>A p.G2312R | Missense Mutation (SNP) | VAF 260/663 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as rs1461788183; called by muse, mutect2, varscan2
- TSHR | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 222/534 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs200182253, COSV99992204; called by muse, varscan2
- TUBE1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs781995006, COSV100898140; called by muse, mutect2, varscan2
- USP54 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 164/434 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1176091575; called by muse, mutect2, varscan2
- UTRN | c.7424G>C p.R2475P | Missense Mutation (SNP) | VAF 162/403 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs771901189, COSV100840755; called by muse, mutect2, varscan2
- VIM | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 192/681 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56405279, COSV99813425; called by muse, mutect2, varscan2
- ZFAND3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54724487; called by muse, mutect2, varscan2
- ZNF132 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 119/666 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as rs372220297; called by muse, mutect2, varscan2
- ZNF432 | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 217/636 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1205791424; called by muse, mutect2, varscan2
- ZNF444 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 148/229 reads (65%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.019); catalogued as rs1234073720; called by muse, mutect2, varscan2
- ZSWIM1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 373/817 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs925443989; called by muse, mutect2, varscan2
- ABCA13 | c.12934C>T p.P4312S | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCB11 | c.2660C>T p.T887I | Missense Mutation (SNP) | VAF 133/621 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACER2 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 633/815 reads (78%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADGRL2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 158/760 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANGPTL6 | c.684A>C p.R228S | Missense Mutation (SNP) | VAF 186/486 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- APOBEC3H | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASIC4 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 313/592 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP2B3 | c.269_286del p.I90_P95del | In Frame Del (DEL) | VAF 177/487 reads (36%) | called by mutect2, pindel, varscan2
- BORCS6 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BRAF | c.1702G>A p.V568I (on ENST00000288602 / NM_001374244.1; = p.V528I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 426/767 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- C4orf47 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 344/600 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- C9orf72 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 28/1054 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- CFHR4 | c.230G>A p.W77* (on ENST00000367416 / NM_001201551.2; = p.W78* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 110/311 reads (35%) | called by muse, mutect2, varscan2
- CNTN1 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 76/762 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CPT1A | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYM | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.188); called by muse, varscan2
- CYP2A7 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 199/451 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DPP6 | c.358G>T p.A120S (on ENST00000377770 / NM_001364500.2; = p.A58S on NM_001936.5) | Missense Mutation (SNP) | VAF 193/362 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DSG2 | c.580T>G p.S194A | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EBF4 | c.1570G>C p.A524P (on ENST00000609451; = p.A520P on NM_001110514.1) | Missense Mutation (SNP) | VAF 81/525 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHX3 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 144/384 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAT1 | c.8990_8991insT p.A2998Gfs*3 | Frame Shift Ins (INS) | VAF 295/659 reads (45%) | called by mutect2, pindel, varscan2
- FIP1L1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 142/239 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FRA10AC1 | c.827-6G>T | Splice Region (SNP) | VAF 113/287 reads (39%) | called by muse, mutect2, varscan2
- FRY | c.2882C>T p.T961I | Missense Mutation (SNP) | VAF 155/493 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FSD2 | c.1498T>A p.S500T | Missense Mutation (SNP) | VAF 180/655 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAS8 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 248/656 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- GNB5 | c.1073C>A p.S358Y (on ENST00000261837 / NM_016194.4; = p.S316Y on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 335/584 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- H4C13 | c.95del p.K32Sfs*35 | Frame Shift Del (DEL) | VAF 185/579 reads (32%) | called by mutect2, pindel, varscan2
- HDAC4 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 154/574 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HINT3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- HNF1B | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 181/461 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HTR3C | c.755T>G p.I252R | Missense Mutation (SNP) | VAF 52/751 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- INTS5 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 154/472 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO8 | c.3104G>A p.S1035N | Missense Mutation (SNP) | VAF 358/697 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIF21B | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 374/698 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIR2DL3 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 148/663 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- KLHL11 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 190/546 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KMT2B | c.4022G>A p.C1341Y | Missense Mutation (SNP) | VAF 190/520 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC36 | c.1205C>G p.A402G | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LRRC49 | c.944_945del p.S315Cfs*15 | Frame Shift Del (DEL) | VAF 245/546 reads (45%) | called by mutect2, pindel, varscan2
- MATN1 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 273/368 reads (74%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MIGA1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 143/707 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MME | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 131/653 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MPRIP | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 147/432 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMS | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 169/725 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTNG1 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 139/599 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PCDHA2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 136/397 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PCDHGA5 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB3 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTBP3 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 287/371 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PZP | c.2299A>C p.T767P | Missense Mutation (SNP) | VAF 126/525 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RABGEF1 | c.1361G>A p.W454* (on ENST00000439720 / NM_001287061.2; = p.W441* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 250/701 reads (36%) | called by muse, mutect2, varscan2
- RASGRP2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 166/418 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- REXO1 | c.2660G>A p.G887D | Missense Mutation (SNP) | VAF 405/510 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF128 | c.593A>T p.K198I (on ENST00000255499 / NM_194463.2; = p.K172I on NM_024539.3) | Missense Mutation (SNP) | VAF 188/553 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- RPL5 | c.73+8C>T | Splice Region (SNP) | VAF 337/901 reads (37%) | called by muse, mutect2, varscan2
- SAGE1 | c.1653G>C p.L551F | Missense Mutation (SNP) | VAF 187/521 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 284/687 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SKOR2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 151/423 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SMAD1 | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 246/471 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SP8 | c.1361G>A p.G454D (on ENST00000361443 / NM_198956.4; = p.G472D on NM_182700.6) | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- STAG1 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 452/680 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by mutect2, varscan2
- STAG1 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- STAG3 | c.2249_2253dup p.S752Ifs*8 | Frame Shift Ins (INS) | VAF 135/431 reads (31%) | called by mutect2, pindel, varscan2
- STMN4 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 184/608 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TEX13D | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.161); called by muse, varscan2
- TLE3 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 378/716 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TLN2 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 155/711 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNS1 | c.3379G>T p.A1127S | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.018); called by muse, mutect2
- TPGS2 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VSTM4 | c.106T>G p.Y36D | Missense Mutation (SNP) | VAF 152/411 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- VWDE | c.4399C>T p.H1467Y | Missense Mutation (SNP) | VAF 170/434 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZBTB11 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 60/442 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF407 | c.4696C>G p.P1566A | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF529 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF606 | c.912T>A p.F304L | Missense Mutation (SNP) | VAF 170/661 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF841 | c.851C>T p.P284L (on ENST00000426391 / NM_001369830.1; = p.P400L on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 206/640 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ACE | c.1311C>T p.I437= | Silent (SNP) | VAF 327/670 reads (49%) | catalogued as rs144657113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS6 | c.21G>A p.T7= | Silent (SNP) | VAF 200/507 reads (39%) | catalogued as COSV66857445; called by muse, mutect2, varscan2
- ANKRD50 | c.2787T>C p.V929= | Silent (SNP) | VAF 124/714 reads (17%) | called by muse, mutect2
- ASL | c.96G>A p.R32= | Silent (SNP) | VAF 136/391 reads (35%) | called by muse, mutect2, varscan2
- BICD2 | c.696C>G p.L232= | Silent (SNP) | VAF 169/458 reads (37%) | catalogued as COSV63550281; called by muse, mutect2, varscan2
- C1QTNF4 | c.702G>A p.T234= | Silent (SNP) | VAF 172/426 reads (40%) | called by muse, mutect2, varscan2
- CAND1 | c.1788T>A p.I596= | Silent (SNP) | VAF 219/746 reads (29%) | called by muse, mutect2, varscan2
- CCDC180 | c.1944G>A p.R648= | Silent (SNP) | VAF 452/551 reads (82%) | called by muse, mutect2, varscan2
- CD99L2 | c.21G>A p.A7= | Silent (SNP) | VAF 128/344 reads (37%) | called by muse, mutect2, varscan2
- CEP350 | c.5445G>A p.K1815= | Silent (SNP) | VAF 122/561 reads (22%) | catalogued as COSV62601267; called by muse, mutect2, varscan2
- CNR1 | c.129C>T p.Y43= | Silent (SNP) | VAF 130/368 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2568G>T p.V856= | Silent (SNP) | VAF 94/398 reads (24%) | catalogued as rs1332465734; called by muse, mutect2, varscan2
- CNTNAP5 | c.153C>T p.G51= | Silent (SNP) | VAF 181/686 reads (26%) | catalogued as rs1452642559, COSV70484149, COSV70500069; called by muse, mutect2, varscan2
- COL24A1 | c.222G>C p.G74= | Silent (SNP) | VAF 26/900 reads (3%) | called by muse, mutect2
- EFCAB8 | c.489C>T p.I163= | Silent (SNP) | VAF 199/1085 reads (18%) | catalogued as rs766269545; called by muse, mutect2, varscan2
- EME2 | c.855C>T p.D285= | Silent (SNP) | VAF 113/319 reads (35%) | catalogued as rs377522534; called by muse, mutect2, varscan2
- EPHA6 | c.1647C>A p.S549= | Silent (SNP) | VAF 175/438 reads (40%) | catalogued as COSV67573776; called by muse, mutect2, varscan2
- ESR2 | c.42C>T p.S14= | Silent (SNP) | VAF 156/434 reads (36%) | catalogued as COSV99963281; called by muse, mutect2, varscan2
- FAT4 | c.3285T>C p.D1095= | Silent (SNP) | VAF 287/485 reads (59%) | called by muse, mutect2, varscan2
- FBXW9 | c.228G>A p.E76= | Silent (SNP) | VAF 136/403 reads (34%) | called by muse, mutect2, varscan2
- FLNA | c.3564G>A p.A1188= | Silent (SNP) | VAF 223/598 reads (37%) | catalogued as rs1434923366, COSV61040859; called by muse, mutect2, varscan2
- FREM3 | c.2631G>A p.L877= | Silent (SNP) | VAF 17/484 reads (4%) | called by muse, mutect2
- FSTL1 | c.453G>A p.K151= | Silent (SNP) | VAF 141/794 reads (18%) | catalogued as rs778663235; called by muse, mutect2, varscan2
- GUCY2F | c.2007G>A p.G669= | Silent (SNP) | VAF 144/380 reads (38%) | called by muse, mutect2, varscan2
- H3-2 | c.87C>T p.S29= | Silent (SNP) | VAF 389/897 reads (43%) | catalogued as COSV67396890; called by muse, mutect2, varscan2
- HDAC9 | c.1269C>T p.P423= | Silent (SNP) | VAF 116/345 reads (34%) | catalogued as COSV67775030; called by muse, mutect2, varscan2
- IGFBP4 | c.294C>T p.G98= | Silent (SNP) | VAF 177/408 reads (43%) | called by muse, mutect2, varscan2
- KNDC1 | c.1113C>T p.H371= | Silent (SNP) | VAF 153/402 reads (38%) | called by muse, varscan2
- LAMB3 | c.2268G>A p.A756= | Silent (SNP) | VAF 311/617 reads (50%) | catalogued as rs779309922; called by muse, mutect2, varscan2
- LRP4 | c.4617C>T p.I1539= | Silent (SNP) | VAF 215/512 reads (42%) | catalogued as rs151261586; called by muse, mutect2, varscan2
- MEGF8 | c.1827G>T p.L609= | Silent (SNP) | VAF 168/565 reads (30%) | called by muse, mutect2, varscan2
- MEP1B | c.579C>T p.D193= | Silent (SNP) | VAF 174/505 reads (34%) | catalogued as rs377157537; called by muse, mutect2, varscan2
- MGRN1 | c.759C>T p.I253= | Silent (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2
- MPDZ | c.4701C>T p.S1567= | Silent (SNP) | VAF 386/510 reads (76%) | called by mutect2, varscan2
- NANOS1 | c.459G>A p.P153= | Silent (SNP) | VAF 92/247 reads (37%) | catalogued as rs762295681; called by muse, mutect2, varscan2
- OBSCN | c.16443G>A p.A5481= | Silent (SNP) | VAF 182/936 reads (19%) | catalogued as rs751562976; called by muse, mutect2, varscan2
- OPHN1 | c.226C>T p.L76= | Silent (SNP) | VAF 172/449 reads (38%) | called by muse, mutect2, varscan2
- P2RX1 | c.954G>A p.L318= | Silent (SNP) | VAF 104/330 reads (32%) | called by muse, mutect2, varscan2
- PARVG | c.564A>C p.T188= | Silent (SNP) | VAF 99/293 reads (34%) | called by muse, mutect2, varscan2
- PPP1R37 | c.1581C>T p.P527= | Silent (SNP) | VAF 130/322 reads (40%) | called by muse, mutect2, varscan2
- PTPRF | c.4959G>A p.T1653= | Silent (SNP) | VAF 477/1109 reads (43%) | catalogued as rs771719646; called by muse, mutect2, varscan2
- RBM10 | c.1722C>T p.Y574= | Silent (SNP) | VAF 147/388 reads (38%) | catalogued as rs375207660; called by muse, mutect2, varscan2
- RHCG | c.651G>A p.S217= | Silent (SNP) | VAF 429/753 reads (57%) | catalogued as rs201741808; called by muse, mutect2, varscan2
- SLC25A4 | c.399G>A p.P133= | Silent (SNP) | VAF 313/530 reads (59%) | catalogued as COSV99861329; called by muse, mutect2, varscan2
- STAG2 | c.3201G>C p.G1067= | Silent (SNP) | VAF 159/422 reads (38%) | catalogued as COSV54368732; called by muse, mutect2, varscan2
- TAF5 | c.2247C>T p.T749= | Silent (SNP) | VAF 200/580 reads (34%) | catalogued as rs370722739; called by muse, mutect2, varscan2
- TARS1 | c.1521A>C p.G507= | Silent (SNP) | VAF 227/538 reads (42%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2409G>A p.Q803= | Silent (SNP) | VAF 180/642 reads (28%) | called by muse, mutect2, varscan2
- TENM3 | c.1626G>A p.P542= | Silent (SNP) | VAF 80/502 reads (16%) | catalogued as rs562866467, COSV69302173; called by muse, mutect2, varscan2
- THOP1 | c.1206G>A p.A402= | Silent (SNP) | VAF 243/297 reads (82%) | catalogued as rs567921382; called by muse, mutect2, varscan2
- TTLL7 | c.636G>A p.S212= | Silent (SNP) | VAF 358/794 reads (45%) | catalogued as rs764286113, COSV53084126; called by muse, mutect2, varscan2
- UBE2G2 | c.321G>A p.A107= | Silent (SNP) | VAF 145/384 reads (38%) | catalogued as rs138889008; called by muse, varscan2
- WDFY4 | c.6081G>A p.Q2027= | Silent (SNP) | VAF 201/528 reads (38%) | catalogued as COSV55429323; called by muse, mutect2, varscan2
- ZDHHC19 | c.324C>T p.A108= | Silent (SNP) | VAF 496/766 reads (65%) | called by muse, mutect2, varscan2
- ZNF827 | c.2199C>T p.S733= | Silent (SNP) | VAF 79/432 reads (18%) | catalogued as rs532889332, COSV101061329; called by muse, mutect2, varscan2
- ZZEF1 | c.8769A>C p.L2923= | Silent (SNP) | VAF 102/323 reads (32%) | called by muse, mutect2, varscan2
- AMFR | c.*84G>A | 3'UTR (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- BOC | c.524-30C>T | Intron (SNP) | VAF 123/646 reads (19%) | called by muse, mutect2, varscan2
- BRD9 | c.-93C>T | 5'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- C17orf49 | c.22-68G>A | Intron (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- CACNA1D | c.1478+343C>T | Intron (SNP) | VAF 145/368 reads (39%) | catalogued as rs370024486; called by muse, varscan2
- CDK18 | c.1269-17G>A | Intron (SNP) | VAF 254/474 reads (54%) | catalogued as rs367550260; called by muse, mutect2, varscan2
- CITED1 | c.*22G>A | 3'UTR (SNP) | VAF 59/156 reads (38%) | catalogued as COSV99860435; called by muse, mutect2, varscan2
- COL13A1 | c.436-21C>G | Intron (SNP) | VAF 77/226 reads (34%) | catalogued as rs1188621211; called by muse, mutect2, varscan2
- CR589904.2 | c.*1075del | 3'UTR (DEL) | VAF 356/440 reads (81%) | catalogued as rs1018908356; called by mutect2, varscan2
- E2F5 | chr8:85214901 A>C | 3'Flank (SNP) | VAF 99/293 reads (34%) | catalogued as COSV56275851; called by muse, mutect2, varscan2
- FRA10AC1 | c.512-57_512-49dup | Intron (INS) | VAF 24/110 reads (22%) | called by mutect2, varscan2
- GTF3C1 | c.*35G>A | 3'UTR (SNP) | VAF 71/207 reads (34%) | called by muse, mutect2, varscan2
- HDAC2 | c.*9G>A | 3'UTR (SNP) | VAF 161/508 reads (32%) | called by muse, mutect2, varscan2
- IPO13 | c.1272-38G>T | Intron (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- JUND | c.-83G>A | 5'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- MAF | c.*4268G>A | 3'UTR (SNP) | VAF 118/356 reads (33%) | catalogued as rs377735141; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85685C>T | Intron (SNP) | VAF 384/660 reads (58%) | catalogued as rs766724008, COSV72280364; called by muse, mutect2, varscan2
- MIGA1 | c.1275+96A>C | Intron (SNP) | VAF 8/211 reads (4%) | called by muse, mutect2
- MROH8 | c.667+19C>T | Intron (SNP) | VAF 312/754 reads (41%) | called by muse, mutect2, varscan2
- MTUS2 | c.3678+26G>A | Intron (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- MUC19 | n.11550C>T | RNA (SNP) | VAF 29/54 reads (54%) | catalogued as rs1372506734; called by muse, mutect2, varscan2
- NXF3 | c.-64C>T | 5'UTR (SNP) | VAF 77/240 reads (32%) | called by muse, mutect2, varscan2
- PATJ | c.4891-47G>A | Intron (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- PCLAF | c.-35G>A | 5'UTR (SNP) | VAF 91/245 reads (37%) | called by muse, mutect2, varscan2
- PCYOX1 | chr2:70258099 del GCGCAGCCGCGCAGCGGTGGGAGGACTGCGGGGCTCTTGAGGCCAGCT | 5'UTR (DEL) | VAF 38/184 reads (21%) | called by mutect2, pindel, varscan2
- PDCD1 | c.*48C>T | 3'UTR (SNP) | VAF 110/227 reads (48%) | catalogued as rs752982737; called by muse, mutect2, varscan2
- PSG4 | c.-39del | 5'UTR (DEL) | VAF 26/102 reads (25%) | called by pindel, varscan2
- PTGR2 | c.730-26T>G | Intron (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- RGS17 | c.*83G>A | 3'UTR (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- RHCE | c.-21C>A | 5'UTR (SNP) | VAF 283/342 reads (83%) | called by muse, mutect2, varscan2
- RSPO3 | c.-62A>T | 5'UTR (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- SGCZ | c.-47T>C | 5'UTR (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1130-62C>T | Intron (SNP) | VAF 85/188 reads (45%) | called by muse, mutect2, varscan2
- TRAF3IP3 | c.1190-62T>A | Intron (SNP) | VAF 47/75 reads (63%) | called by muse, mutect2, varscan2
- TSHZ3 | c.-75C>T | 5'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- WBP2 | c.-14C>T | 5'UTR (SNP) | VAF 196/404 reads (49%) | catalogued as rs1475663475; called by muse, mutect2, varscan2
- ZNF880 | c.*50A>T | 3'UTR (SNP) | VAF 76/170 reads (45%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.746-28T>C | Intron (SNP) | VAF 43/208 reads (21%) | catalogued as rs751208883; called by muse, mutect2, varscan2
